Somatic mutation profile of tumor specimen TCGA-FG-A6J3-01A (aliquot TCGA-FG-A6J3-01A-11D-A31L-08) from TCGA case TCGA-FG-A6J3, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Astrocytoma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 52.4 years (19,138 days).
Specimen TCGA-FG-A6J3-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8752685f-ed80-4684-8174-858747f4ac1c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FG-A6J3-10A (Blood Derived Normal), aliquot TCGA-FG-A6J3-10A-01D-A31J-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a55d53ef-c14a-4d5c-a047-88bee1c995bd

The open-access MAF lists 76 somatic variants for this specimen: 57 protein-altering or splice-affecting, 17 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 51, Silent 17, Nonsense Mutation 4, 3'UTR 1, RNA 1, Frame Shift Ins 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 11/55 reads (20%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.715_723del p.N239_S241del | In Frame Del (DEL) | VAF 30/43 reads (70%) | hotspot (GDC flag); called by mutect2, pindel, varscan2
- A2M | c.2411G>C p.R804P | Missense Mutation (SNP) | VAF 107/277 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100588744; called by muse, mutect2, varscan2
- AIFM1 | c.764A>T p.K255M | Missense Mutation (SNP) | VAF 14/98 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99781098; called by muse, mutect2, varscan2
- ANKRD30A | c.3465A>T p.E1155D (on ENST00000611781; = p.E1099D on NM_052997.2) | Missense Mutation (SNP) | VAF 39/229 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.264); catalogued as COSV100653693; called by muse, mutect2, varscan2
- ANKRD30A | c.3749A>G p.H1250R (on ENST00000611781; = p.H1194R on NM_052997.2) | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.125); catalogued as rs934222383, COSV100653694; called by muse, mutect2, varscan2
- ARHGAP36 | c.1263C>A p.N421K | Missense Mutation (SNP) | VAF 38/256 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.903); catalogued as COSV99357806; called by muse, mutect2, varscan2
- BRD1 | c.509A>G p.N170S | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1436656382, COSV99349898; called by muse, mutect2, varscan2
- CAMSAP1 | c.3882G>C p.Q1294H | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100409979; called by muse, mutect2, varscan2
- CDX4 | c.446C>A p.P149H | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.95); catalogued as COSV100999138; called by muse, mutect2, varscan2
- CEP70 | c.146G>A p.R49K | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.83); PolyPhen benign (0.007); catalogued as rs1250694077, COSV53877264; called by muse, mutect2, varscan2
- CFAP91 | c.1813C>T p.R605C | Missense Mutation (SNP) | VAF 16/113 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs142545565; called by muse, mutect2, varscan2
- CHP2 | c.556G>T p.V186F | Missense Mutation (SNP) | VAF 38/220 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.145); catalogued as rs149498782, COSV100270182; called by muse, mutect2, varscan2
- COL21A1 | c.1529G>A p.R510Q | Missense Mutation (SNP) | VAF 43/77 reads (56%) | SIFT tolerated (0.51); PolyPhen benign (0.023); catalogued as COSV55158678, COSV99777539; called by muse, mutect2, varscan2
- CTNND1 | c.404G>A p.R135Q | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.493); catalogued as rs767448387, COSV100650151; called by muse, mutect2, varscan2
- DIAPH2 | c.896C>A p.T299K | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100233316; called by mutect2, varscan2
- DNAJA2 | c.452G>A p.G151E | Missense Mutation (SNP) | VAF 37/164 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100398874; called by muse, mutect2, varscan2
- EDRF1 | c.2693A>G p.N898S (on ENST00000356792 / NM_001202438.2; = p.N864S on NM_015608.2) | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1240567346, COSV100523565; called by muse, mutect2, varscan2
- F13B | c.644C>T p.S215F | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.14); PolyPhen benign (0.063); catalogued as COSV100803324; called by muse, mutect2, varscan2
- FCRL5 | c.82C>T p.Q28* | Nonsense Mutation (SNP) | VAF 33/140 reads (24%) | catalogued as COSV100709010, COSV62520047; called by muse, mutect2, varscan2
- GPR37L1 | c.1231A>G p.I411V | Missense Mutation (SNP) | VAF 33/77 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100938560; called by muse, mutect2, varscan2
- HLA-DRA | c.223C>T p.R75* | Nonsense Mutation (SNP) | VAF 29/199 reads (15%) | catalogued as rs754420534, COSV66623242; called by muse, mutect2, varscan2
- IGHV1-18 | c.284C>T p.T95M | Missense Mutation (SNP) | VAF 75/212 reads (35%) | SIFT tolerated (0.16); PolyPhen benign (0.09); catalogued as rs782350295; called by muse, varscan2
- IL7R | c.532T>C p.W178R | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100286332; called by muse, mutect2, varscan2
- ITPR3 | c.346G>A p.V116M | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs768293062, COSV100967502; called by muse, mutect2, varscan2
- KCNG4 | c.751G>A p.D251N | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0.022); catalogued as rs1485281578, COSV100377090; called by muse, mutect2, varscan2
- KRT36 | c.808G>A p.E270K | Missense Mutation (SNP) | VAF 35/154 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as rs763099092, COSV60203026; called by muse, mutect2, varscan2
- LRRK1 | c.499G>A p.G167R | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.076); catalogued as COSV99440694; called by muse, mutect2, varscan2
- MAGEB6B | c.734C>T p.T245M | Missense Mutation (SNP) | VAF 17/121 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.261); catalogued as COSV101301710; called by muse, mutect2, varscan2
- MCC | c.1348C>G p.Q450E | Missense Mutation (SNP) | VAF 31/101 reads (31%) | SIFT tolerated (1); PolyPhen possibly damaging (0.736); catalogued as COSV100202764; called by muse, mutect2, varscan2
- MUC2 | c.1585G>A p.G529R | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1406517857; called by muse, mutect2, varscan2
- NBEAL1 | c.5329G>C p.A1777P | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.307); catalogued as COSV101495724; called by muse, mutect2, varscan2
- OGDHL | c.1966A>G p.I656V | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT tolerated (0.38); PolyPhen benign (0.012); catalogued as rs1412661966, COSV100934372; called by muse, mutect2
- OR51B5 | c.38C>T p.T13I | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.973); catalogued as COSV100332562, COSV56175462; called by muse, mutect2, varscan2
- PATJ | c.2483A>G p.E828G | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.205); catalogued as COSV100334418; called by muse, mutect2
- PKHD1L1 | c.9786A>T p.K3262N | Missense Mutation (SNP) | VAF 15/183 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.858); catalogued as COSV101006299, COSV65755840; called by muse, mutect2
- PLCE1 | c.3748G>A p.E1250K | Missense Mutation (SNP) | VAF 21/108 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.03); catalogued as rs775639600, COSV53344642, COSV53346464; called by muse, mutect2, varscan2
- PROSER3 | c.1306G>T p.A436S | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.27); catalogued as COSV99994585; called by mutect2, varscan2
- PTPDC1 | c.742C>T p.R248C (on ENST00000375360 / NM_177995.3; = p.R300C on NM_152422.4) | Missense Mutation (SNP) | VAF 25/160 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs760421150, COSV99997675; called by muse, mutect2, varscan2
- PTPRH | c.2433G>T p.K811N | Missense Mutation (SNP) | VAF 11/121 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.033); catalogued as COSV99671108; called by muse, mutect2
- RTN3 | c.1424A>G p.D475G (on ENST00000377819 / NM_001265589.2; = p.D456G on NM_201428.3) | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT tolerated (0.71); PolyPhen benign (0.005); catalogued as COSV100380219; called by muse, mutect2, varscan2
- SERPINB4 | c.241G>A p.V81I | Missense Mutation (SNP) | VAF 6/105 reads (6%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.879); catalogued as COSV100345780; called by muse, mutect2
- SERPINB8 | c.955G>A p.V319M | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs375110009; called by muse, mutect2, varscan2
- SETD2 | c.4954A>C p.T1652P | Missense Mutation (SNP) | VAF 48/199 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100339219; called by muse, mutect2, varscan2
- SMYD4 | c.241G>T p.E81* | Nonsense Mutation (SNP) | VAF 28/171 reads (16%) | catalogued as COSV100563075; called by muse, mutect2, varscan2
- SS18L1 | c.256G>A p.G86S | Missense Mutation (SNP) | VAF 21/91 reads (23%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.994); catalogued as COSV100064999; called by muse, mutect2, varscan2
- SULT2B1 | c.907G>T p.G303W (on ENST00000201586 / NM_177973.2; = p.G288W on NM_004605.2) | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs375751466, COSV99572266; called by muse, varscan2
- SYNPO2 | c.821G>T p.S274I | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.48); PolyPhen benign (0.043); catalogued as COSV100205765; called by muse, mutect2, varscan2
- TBC1D4 | c.2447C>T p.P816L | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.222); catalogued as rs766624952, COSV100884640; called by muse, mutect2, varscan2
- TINAG | c.571C>T p.R191C | Missense Mutation (SNP) | VAF 26/123 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as rs115438249, COSV52508165; called by muse, mutect2, varscan2
- TLCD3A | c.397C>T p.P133S | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100021416; called by muse, mutect2
- TMEM144 | c.322G>A p.A108T | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.138); catalogued as COSV99646843; called by muse, mutect2
- TTN | c.6813A>T p.K2271N (on ENST00000591111; = p.K2225N on NM_003319.4) | Missense Mutation (SNP) | VAF 4/24 reads (17%) | PolyPhen probably damaging (0.997); catalogued as COSV100617456; called by muse, mutect2, varscan2
- UPF1 | c.1027G>A p.A343T | Missense Mutation (SNP) | VAF 15/111 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.597); catalogued as COSV53194973; called by muse, mutect2, varscan2
- YTHDC2 | c.725G>A p.R242H | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); catalogued as COSV50748251; called by muse, mutect2, varscan2
- ACACA | c.6610A>T p.K2204* | Nonsense Mutation (SNP) | VAF 20/138 reads (14%) | called by muse, mutect2, varscan2
- IGHV1-18 | c.317dup p.S107Ifs*2 | Frame Shift Ins (INS) | VAF 49/252 reads (19%) | called by pindel, varscan2
- ADAM9 | c.1809G>A p.V603= | Silent (SNP) | VAF 16/77 reads (21%) | catalogued as COSV101166140; called by muse, mutect2, varscan2
- ANAPC1 | c.5325C>G p.L1775= | Silent (SNP) | VAF 11/83 reads (13%) | catalogued as COSV100594821; called by mutect2, varscan2
- CALR3 | c.642G>A p.S214= | Silent (SNP) | VAF 8/42 reads (19%) | catalogued as rs200669493, COSV99522222; ClinVar: likely benign; called by muse, mutect2, varscan2
- DDTL | c.370T>C p.L124= | Silent (SNP) | VAF 15/76 reads (20%) | catalogued as COSV99303791; called by muse, mutect2, varscan2
- DSG3 | c.2382T>C p.S794= | Silent (SNP) | VAF 57/109 reads (52%) | catalogued as rs1288306484, COSV57128613, COSV99934308; called by muse, mutect2, varscan2
- FGF6 | c.513C>T p.Y171= | Silent (SNP) | VAF 36/508 reads (7%) | catalogued as rs542608820, COSV99960283; called by muse, mutect2
- KCNQ3 | c.426G>T p.L142= | Silent (SNP) | VAF 6/40 reads (15%) | catalogued as COSV101196195; called by muse, mutect2, varscan2
- KIAA1217 | c.138C>T p.R46= | Silent (SNP) | VAF 10/40 reads (25%) | catalogued as COSV100908045; called by muse, mutect2, varscan2
- MYH9 | c.5097C>T p.A1699= | Silent (SNP) | VAF 24/69 reads (35%) | catalogued as COSV99339095; called by muse, mutect2, varscan2
- NHS | c.861C>A p.P287= | Silent (SNP) | VAF 7/57 reads (12%) | catalogued as COSV101196696; called by muse, mutect2, varscan2
- PLEKHM2 | c.2985G>A p.L995= | Silent (SNP) | VAF 40/94 reads (43%) | catalogued as COSV99606659; called by muse, mutect2, varscan2
- PRAMEF12 | c.1047C>A p.T349= | Silent (SNP) | VAF 10/100 reads (10%) | catalogued as rs371643266; called by muse, mutect2, varscan2
- RYR3 | c.5289G>A p.E1763= | Silent (SNP) | VAF 35/137 reads (26%) | catalogued as rs769507366, COSV101212975; called by muse, mutect2, varscan2
- SLC36A2 | c.670T>C p.L224= | Silent (SNP) | VAF 10/25 reads (40%) | catalogued as COSV100079197; called by muse, mutect2, varscan2
- STAT5B | c.1245C>T p.H415= | Silent (SNP) | VAF 16/79 reads (20%) | catalogued as COSV99511024; called by muse, mutect2, varscan2
- ZBTB24 | c.2076T>A p.L692= | Silent (SNP) | VAF 39/81 reads (48%) | catalogued as COSV100018493; called by muse, mutect2, varscan2
- ZP2 | c.387C>T p.H129= | Silent (SNP) | VAF 53/138 reads (38%) | catalogued as rs776072365, COSV54817633; called by muse, mutect2, varscan2
- AGAP7P | n.1509C>T | RNA (SNP) | VAF 35/170 reads (21%) | called by muse, mutect2, varscan2
- DDX41 | c.*962G>A | 3'UTR (SNP) | VAF 14/47 reads (30%) | catalogued as COSV100394385; called by muse, mutect2, varscan2
